FM case AD191 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/67abd65e-79ee-4cb8-bccd-ade2b47deb19

Female, 41.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the cervix uteri. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
